Somatic mutation profile of tumor specimen 0DU817 from CCDI case PBCKGH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 10.1 years (3,672 days).
Specimen 0DU817: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aea61e35-bb4a-48bc-9fea-e740bda49fa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU807 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea5c333f-5fab-43cf-803c-8eee6275392c

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Nonsense Mutation 1, RNA 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAFAH1B1 | c.1229G>C p.R410P | Missense Mutation (SNP) | VAF 628/1386 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUCNR1 | c.321T>A p.Y107* | Nonsense Mutation (SNP) | VAF 248/1078 reads (23%) | called by muse, mutect2, varscan2
- AP1B1 | c.1368G>C p.A456= | Silent (SNP) | VAF 601/3061 reads (20%) | catalogued as COSV100434899; called by muse, mutect2, varscan2
- TMEM131L | c.4437C>T p.G1479= | Silent (SNP) | VAF 255/1593 reads (16%) | called by muse, mutect2, varscan2
- C5orf60 | n.1669G>A | RNA (SNP) | VAF 168/1586 reads (11%) | called by muse, mutect2, varscan2
